Somatic mutation profile of tumor specimen TCGA-A2-A25A-01A (aliquot TCGA-A2-A25A-01A-12D-A16D-09) from TCGA case TCGA-A2-A25A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 44.0 years (16,084 days).
Specimen TCGA-A2-A25A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89af4c02-87eb-440b-9ac0-44b0ba52700a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A25A-10A (Blood Derived Normal), aliquot TCGA-A2-A25A-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3512749-c9b5-46e6-9d1b-8b4e5dcd0a16

The open-access MAF lists 282 somatic variants for this specimen: 215 protein-altering or splice-affecting, 60 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 60, Nonsense Mutation 14, 3'Flank 3, Intron 2, Splice Site 1, RNA 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1060501244, CM041747, COSV55728376; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- HBA2 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs33933481, CM810008, COSV52406347; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.389C>A p.P130H (on ENST00000373394 / NM_001271696.3; = p.P131H on NM_004299.6) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99504785, COSV99504861; called by muse, mutect2
- ACTR8 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.124); catalogued as COSV51635237; called by muse, mutect2
- ADAMTS14 | c.1791G>T p.E597D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV100941883; called by muse, mutect2
- ADAMTS3 | c.3507C>A p.F1169L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV54386153; called by muse, mutect2, varscan2
- ADD3 | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99523748; called by muse, mutect2
- ADGRV1 | c.12487G>T p.G4163W | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101316547; called by muse, mutect2
- AGPAT4 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as COSV57243360; called by muse, mutect2, varscan2
- AIFM1 | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV54852852; called by muse, mutect2
- ANKRD6 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs1240873114, COSV100330353; called by muse, mutect2
- ARGFX | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV57681671; called by muse, mutect2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2, varscan2
- ASF1A | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV57647313, COSV57648163; called by muse, mutect2, varscan2
- ASH1L | c.5070G>C p.E1690D | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV64205912; called by muse, mutect2, varscan2
- ASPM | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54125658; called by muse, mutect2
- ASXL2 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1217311360, COSV55454395, COSV55456678; called by muse, mutect2, varscan2
- ATAD2B | c.3967G>A p.E1323K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.274); catalogued as COSV99478495; called by muse, mutect2
- ATP2B1 | c.2063C>A p.P688H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53804523; called by muse, mutect2, varscan2
- B4GALNT4 | c.2893G>T p.G965C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321910; called by mutect2, varscan2
- BRSK2 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100373196; called by muse, mutect2
- BTN3A1 | c.944G>T p.R315I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50024528; called by muse, mutect2
- C4BPB | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99699805, COSV99700183; called by muse, mutect2
- C5orf24 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV100574579; called by muse, mutect2, varscan2
- CACNA1A | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1314131351, COSV100803268; called by muse, mutect2, varscan2
- CACNA1I | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100361589, COSV60811825; called by muse, mutect2, varscan2
- CARF | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100247919; called by muse, mutect2
- CARS1 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99543581; called by muse, mutect2
- CCDC163 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV101284477; called by muse, mutect2, varscan2
- CCDC82 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1170011769, COSV99567576; called by muse, mutect2
- CCDC87 | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100040193; called by muse, mutect2
- CDC40 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57008055, COSV57008082; called by muse, mutect2, varscan2
- CDC42BPA | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs767024673, COSV62003387, COSV62003849; called by muse, mutect2, varscan2
- CDC7 | c.1272G>T p.L424F | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319957; called by muse, mutect2
- CDK5RAP2 | c.4591C>A p.Q1531K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV62572380; called by muse, mutect2, varscan2
- CFAP54 | c.6955G>T p.A2319S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100733359; called by muse, mutect2
- CHEK2 | c.1051G>C p.E351Q (on ENST00000382580 / NM_001005735.2; = p.E308Q on NM_007194.4) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60416556; called by muse, mutect2, varscan2
- COL11A1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617853; called by muse, mutect2
- COL3A1 | c.2590G>T p.G864C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483764; called by muse, mutect2
- CSTL1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99851222; called by muse, mutect2
- CWC22 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 9/149 reads (6%) | catalogued as COSV99844043, COSV99844671; called by muse, mutect2
- CYP24A1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53776474; called by muse, mutect2
- CYP26A1 | c.1393T>A p.W465R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56417314; called by muse, mutect2, varscan2
- DCDC2 | c.1421C>A p.A474D | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101015550; called by muse, mutect2
- DDX42 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100835086; called by muse, mutect2
- DDX58 | c.2549C>A p.P850Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV100008679; called by muse, mutect2
- DICER1 | c.3037C>A p.P1013T | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100602549, COSV100602570; called by muse, mutect2
- DNAH10 | c.3565G>T p.D1189Y (on ENST00000409039; = p.D1128Y on NM_207437.3) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV68988918; called by muse, mutect2, varscan2
- DNAJC6 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV99675697; called by muse, mutect2
- DNAJC7 | c.289C>A p.R97= | Splice Region (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100348138, COSV57270952; called by muse, mutect2
- DNMBP | c.4604C>A p.S1535* | Nonsense Mutation (SNP) | VAF 25/224 reads (11%) | catalogued as COSV60621289; called by muse, mutect2, varscan2
- DOCK1 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 15/207 reads (7%) | catalogued as COSV99726240; called by muse, mutect2
- DOP1B | c.6418G>T p.E2140* | Nonsense Mutation (SNP) | VAF 11/135 reads (8%) | catalogued as COSV101215862, COSV67692182, COSV67692577; called by muse, mutect2
- DSCC1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100558424; called by muse, mutect2, varscan2
- EIF4A2 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99961391; called by muse, mutect2
- EIF4EBP2 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100947023; called by muse, mutect2
- EML1 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV51742104; called by muse, mutect2, varscan2
- EPHA3 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100348975; called by muse, mutect2
- ERI3 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV64830337; called by muse, mutect2, varscan2
- ERMP1 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99284793; called by muse, mutect2
- ESRP1 | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619675; called by muse, mutect2
- ETAA1 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.095); catalogued as COSV99712961; called by muse, mutect2
- FAM122B | c.737C>A p.P246H (on ENST00000370790 / NM_001166599.3; = p.P247H on NM_145284.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99980508; called by muse, mutect2
- FAM214A | c.3073C>A p.L1025M | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935626711, COSV55926913; called by muse, mutect2
- FGF16 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101466328; called by muse, mutect2
- FHL5 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58735504; called by mutect2, varscan2
- FLOT2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs751666905, COSV67528858, COSV67529363; called by muse, mutect2, varscan2
- FREM2 | c.6848C>T p.S2283L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99751059; called by muse, mutect2
- FREM2 | c.9245G>A p.R3082H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs149553690; called by mutect2, varscan2
- FUCA1 | c.456C>A p.N152K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100991614; called by muse, mutect2
- GARS1 | c.2099C>G p.S700C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV101220293; called by muse, mutect2
- GBA2 | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62306635; called by muse, mutect2
- GLRA4 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.445); catalogued as rs1569416397, COSV60327319; called by muse, mutect2, varscan2
- GPX7 | c.434G>T p.W145L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100790964; called by mutect2, varscan2
- H3-3A | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100831358; called by muse, mutect2
- HCRTR2 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs777851245, COSV63794051, COSV63794610; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2, varscan2
- HEG1 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100230957; called by muse, mutect2
- HPCAL4 | c.69C>A p.S23R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV65716060; called by muse, mutect2, varscan2
- HTR3D | c.781G>T p.A261S (on ENST00000382489 / NM_001163646.2; = p.A88S on NM_182537.3) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100488370; called by muse, mutect2
- IGF2R | c.6655G>T p.D2219Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100808231; called by muse, mutect2
- IL18R1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127062, COSV52127533; called by muse, mutect2
- ITPR1 | c.5151G>T p.E1717D (on ENST00000354582; = p.E1710D on NM_001168272.2) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100233285; called by muse, mutect2
- KCNK18 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100572146; called by muse, mutect2
- KDM1B | c.1966G>T p.G656C (on ENST00000449850; = p.G423C on NM_153042.4) | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924700; called by muse, mutect2
- KHDRBS2 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55430597; called by muse, mutect2, varscan2
- KIAA0319L | c.1853T>A p.L618Q | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100357730; called by muse, mutect2
- KIF5A | c.2869C>G p.L957V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV54052036, COSV99672236; called by muse, mutect2, varscan2
- KLHL20 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268677; called by muse, mutect2
- KLHL5 | c.2205G>T p.W735C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785945; called by muse, mutect2, varscan2
- KPNA1 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100724155, COSV60271902; called by muse, mutect2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2, varscan2
- L3HYPDH | c.1041G>C p.L347F | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99904564; called by muse, mutect2
- LAMA4 | c.3848C>A p.S1283Y (on ENST00000230538 / NM_001105206.3; = p.S1276Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100039499; called by muse, mutect2
- LAMB3 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV50520373, COSV50520684; called by muse, varscan2
- LCN1 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99704550; called by muse, mutect2
- LIPF | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99490632; called by muse, mutect2
- LYST | c.8484C>A p.C2828* | Nonsense Mutation (SNP) | VAF 30/278 reads (11%) | catalogued as COSV101090337; called by muse, mutect2
- MAG | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV62699235; called by muse, mutect2, varscan2
- MAGEB1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs113819941, COSV66775289; called by mutect2, varscan2
- MAN1A2 | c.1860G>T p.E620D | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100741010; called by muse, mutect2
- MANBA | c.1823C>A p.S608Y (on ENST00000642252; = p.S562Y on NM_005908.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56963168; called by mutect2, varscan2
- MAP3K13 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408006; called by muse, mutect2
- MAP3K4 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV62330511; called by muse, mutect2, varscan2
- MARF1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); catalogued as rs1162083192, COSV100706388; called by muse, mutect2, varscan2
- MARK1 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV65065893, COSV65067743; called by muse, mutect2
- MAST2 | c.3928G>T p.G1310C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100788794, COSV63621363; called by muse, mutect2
- MBTPS1 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100597829; called by muse, mutect2
- MED12 | c.2499C>G p.F833L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV61333279; called by muse, mutect2, varscan2
- MICU1 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100741948, COSV63145699; called by muse, mutect2
- MID2 | c.1346G>T p.S449I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99465669; called by muse, mutect2
- MITF | c.1011-1G>T p.X337_splice (on ENST00000448226 / NM_006722.3; = p.X237_splice on NM_000248.4) | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100097465; called by muse, mutect2
- MKI67 | c.8210C>A p.P2737H | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100897012; called by muse, mutect2
- MLLT3 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV100581658; called by muse, mutect2
- MPHOSPH8 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64054503, COSV64055254; called by muse, mutect2
- MTPAP | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV99554327; called by muse, mutect2
- MUC16 | c.12995C>A p.S4332Y | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV101201784, COSV67488218; called by muse, mutect2
- MUC16 | c.8254C>A p.P2752T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV101201785; called by muse, mutect2
- MUC21 | c.918_962del p.N313_A327del | In Frame Del (DEL) | VAF 4/48 reads (8%) | catalogued as rs1261610710; called by mutect2*, pindel
- MYH1 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99875413; called by muse, mutect2
- NAA16 | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101038418; called by muse, mutect2
- NDST1 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55790574; called by muse, varscan2
- NETO1 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.161); catalogued as COSV100199783, COSV55001970; called by muse, mutect2
- NEUROD6 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV99774205; called by muse, mutect2
- NLRP11 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100789817, COSV100789833; called by muse, mutect2
- NLRP4 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017185; called by muse, mutect2
- NOL8 | c.2190C>A p.D730E | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100694701; called by muse, mutect2
- NPC1L1 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99213551; called by muse, mutect2
- NRDC | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV100703902; called by muse, mutect2
- NRXN2 | c.3029C>A p.P1010Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.565); catalogued as COSV99635892; called by muse, mutect2
- NUP98 | c.4957C>A p.H1653N (on ENST00000359171 / NM_001365126.1; = p.H1636N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100263498; called by muse, mutect2
- OGDHL | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65101247; called by muse, varscan2
- OGN | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99364310; called by muse, mutect2
- OR2M7 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 37/399 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.69); catalogued as COSV100522697, COSV58739236; called by muse, mutect2
- OR8B3 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV63541317; called by muse, mutect2, varscan2
- OR8K1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762372416, COSV54401578, COSV99687245; called by muse, mutect2, varscan2
- OSER1 | c.180C>A p.D60E | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV99667448; called by muse, mutect2
- OSMR | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV57081618; called by muse, mutect2, varscan2
- PAK2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100506372; called by muse, mutect2
- PALM2AKAP2 | c.460C>G p.L154V (on ENST00000374531 / NM_001037293.2; = p.L186V on NM_053016.6) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV100093709; called by muse, mutect2
- PAPOLG | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV99475125; called by muse, mutect2
- PARP1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.189); catalogued as rs377195931; called by muse, mutect2, varscan2
- PCDH1 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54611587; called by muse, mutect2, varscan2
- PCDHB11 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs367801902; called by muse, varscan2
- PDCD4 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99701201; called by muse, mutect2
- PEX12 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99862252; called by muse, mutect2
- PHC3 | c.602C>A p.S201* (on ENST00000494943 / NM_001308116.2; = p.S213* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100767241, COSV100767255; called by muse, mutect2
- PIAS1 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs763915443, COSV51030394, COSV99987178; called by muse, varscan2
- PIAS1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764996234, COSV51030416, COSV99986783; called by muse, varscan2
- PIN4 | c.261G>A p.M87I (on ENST00000664196; = p.M62I on NM_006223.4) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99512566; called by muse, mutect2
- PLPP3 | c.866C>G p.P289R | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100984820; called by muse, mutect2
- PLXNC1 | c.2300G>T p.S767I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99313886; called by muse, mutect2
- POLR1G | c.777A>T p.K259N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99185401; called by muse, mutect2
- PPIL2 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV58608354, COSV58609036; called by muse, mutect2
- PTPN1 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791368; called by muse, mutect2
- PTPRK | c.4034C>A p.P1345H (on ENST00000368215 / NM_001291984.2; = p.P1346H on NM_002844.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63891984; called by muse, mutect2
- RAB3A | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55851924, COSV55852014; called by muse, mutect2, varscan2
- RAPGEF1 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100940798, COSV64699972; called by muse, mutect2
- RAPGEF2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52425304; called by muse, mutect2, varscan2
- RASGRF2 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen possibly damaging (0.475); catalogued as COSV99430485; called by muse, mutect2
- RASGRP1 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100172325; called by muse, mutect2
- RBBP8 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091014; called by muse, mutect2, varscan2
- RNF115 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | catalogued as COSV100991926; called by muse, mutect2
- RNF40 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.202); catalogued as COSV61213867, COSV61216276; called by muse, mutect2, varscan2
- RRM2 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as COSV58815971; called by muse, mutect2, varscan2
- SELP | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55248866; called by muse, mutect2, varscan2
- SLC10A3 | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54836708, COSV99682278; called by muse, mutect2
- SLC12A6 | c.1307C>A p.P436H (on ENST00000354181 / NM_001365088.1; = p.P385H on NM_005135.2) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99270686; called by muse, mutect2
- SLC25A12 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99785439; called by muse, mutect2
- SLC30A9 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV100048527; called by mutect2, varscan2
- SLC35G1 | c.206G>T p.G69V (on ENST00000427197 / NM_001134658.3; = p.G68V on NM_153226.4) | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV101004117; called by muse, mutect2
- SLC36A1 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as COSV54656885, COSV99695774; called by muse, mutect2
- SLCO4A1 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53889438; called by mutect2, varscan2
- SLITRK5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61525515; called by muse, mutect2
- SMYD3 | c.195C>A p.C65* (on ENST00000490107 / NM_001375962.1; = p.C6* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/151 reads (6%) | catalogued as COSV101194640; called by muse, mutect2
- SMYD4 | c.2347C>A p.Q783K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV54617741; called by muse, mutect2
- SPAG6 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57624688; called by muse, mutect2
- SPOCK1 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV56438437; called by muse, mutect2, varscan2
- SPRYD3 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100036649; called by muse, mutect2, varscan2
- STRIP1 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV100874113; called by muse, mutect2
- SUPT6H | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58924997; called by muse, mutect2, varscan2
- SVEP1 | c.2255C>A p.T752N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100239139; called by muse, mutect2
- SVOP | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100139677; called by muse, mutect2
- TAF12 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99847527; called by muse, mutect2
- TAF1C | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV100499797; called by muse, mutect2
- TARS2 | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946118; called by muse, mutect2
- TBC1D31 | c.2774G>T p.R925M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV54864099; called by muse, mutect2, varscan2
- TBL1XR1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV101467814; called by muse, mutect2
- TBX3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57470909; called by muse, mutect2, varscan2
- TCHH | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.043); catalogued as COSV100915501; called by muse, mutect2
- TEK | c.2924A>G p.N975S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV101193577; called by muse, mutect2
- TEX264 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV58133534; called by muse, mutect2, varscan2
- TF | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99396439; called by muse, mutect2
- THSD7A | c.1118C>A p.S373* | Nonsense Mutation (SNP) | VAF 11/147 reads (7%) | catalogued as COSV101448916; called by muse, mutect2
- THYN1 | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1474962757; called by muse, mutect2
- TMEM214 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as COSV99476548; called by muse, mutect2
- TMEM67 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV60036541; called by muse, mutect2, varscan2
- TOP3B | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100592827; called by mutect2, varscan2
- ULK2 | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV64444461; called by mutect2, varscan2
- VPS13C | c.2519C>A p.A840D (on ENST00000644861 / NM_020821.3; = p.A797D on NM_017684.5) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51198038, COSV99830304; called by muse, mutect2
- VPS39 | c.2603C>A p.P868H (on ENST00000348544 / NM_001301138.2; = p.P857H on NM_015289.5) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529635; called by muse, mutect2
- WARS2 | c.877C>A p.R293S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99346811; called by mutect2, varscan2
- WDR19 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99975949; called by muse, mutect2
- XAGE5 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100657848; called by muse, mutect2
- ZC3H10 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99230628; called by muse, mutect2, varscan2
- ZNF554 | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV57884565; called by muse, mutect2, varscan2
- ZNFX1 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100871019; called by muse, mutect2
- ESYT1 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- KCNJ3 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.115); called by muse, mutect2
- KRT76 | c.1294del p.A432Lfs*40 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | called by mutect2, pindel, varscan2
- POLR2A | c.4820G>T p.G1607V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2
- STAP1 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- TTC17 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.551); called by muse, mutect2
- XAGE2 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 19/489 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2
- ABCB5 | c.3147G>T p.V1049= (on ENST00000404938 / NM_001163941.2; = p.V604= on NM_178559.6) | Silent (SNP) | VAF 13/243 reads (5%) | catalogued as COSV99329742; called by muse, mutect2
- ABCC2 | c.3738C>G p.L1246= | Silent (SNP) | VAF 55/318 reads (17%) | catalogued as COSV64984822; called by muse, mutect2, varscan2
- ADGRE5 | c.597C>A p.P199= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV99663297; called by muse, mutect2
- AFF3 | c.3150C>A p.G1050= | Silent (SNP) | VAF 31/343 reads (9%) | catalogued as COSV57871197; called by muse, mutect2
- CCAR2 | c.474C>G p.L158= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs1189722007, COSV51514537; called by muse, mutect2, varscan2
- CENPE | c.5529G>A p.Q1843= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as COSV99479216; called by muse, mutect2
- CEP350 | c.4404G>T p.V1468= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as COSV100855269; called by muse, mutect2
- CNOT11 | c.1443C>T p.F481= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as COSV99179390; called by muse, mutect2
- CRTAC1 | c.57C>A p.L19= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV100086156; called by muse, mutect2
- DCLK2 | c.432C>T p.Y144= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1016284361, COSV56211585; called by muse, mutect2
- DHRS3 | c.672C>T p.T224= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs758538732, COSV100879692; called by mutect2, varscan2
- DLG2 | c.597C>A p.G199= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as COSV99719876; called by muse, mutect2
- DNAJC7 | c.288C>A p.V96= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100348141; called by muse, mutect2
- DOCK3 | c.5541G>T p.L1847= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56505993; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2037C>A p.S679= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV100349407; called by muse, mutect2
- EIF4G1 | c.4575C>T p.L1525= (on ENST00000346169 / NM_198241.3; = p.L1330= on NM_004953.5) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs139865627; called by mutect2, varscan2
- GRK1 | c.757C>T p.L253= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV100175472; called by muse, mutect2, varscan2
- H2AC1 | c.234C>A p.R78= | Silent (SNP) | VAF 25/418 reads (6%) | catalogued as COSV99219581; called by muse, mutect2
- HAVCR2 | c.384C>A p.V128= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV57154953, COSV57155566; called by muse, mutect2
- HHATL | c.294C>A p.R98= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV60041050; called by muse, mutect2, varscan2
- HMGN5 | c.180C>A p.A60= | Silent (SNP) | VAF 62/305 reads (20%) | catalogued as rs1462069697, COSV63916442; called by muse, mutect2, varscan2
- HRNR | c.57C>A p.A19= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as rs1220124081, COSV100913703; called by muse, mutect2
- HSPA9 | c.1041C>A p.T347= | Silent (SNP) | VAF 9/177 reads (5%) | catalogued as COSV99785687; called by muse, mutect2
- IGF2BP2 | c.921G>A p.K307= | Silent (SNP) | VAF 35/349 reads (10%) | catalogued as COSV100649536; called by muse, mutect2, varscan2
- KMT2A | c.4101G>T p.P1367= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100629944, COSV63293501; called by muse, mutect2, varscan2
- KRT35 | c.498C>A p.A166= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- LYG2 | c.492C>A p.P164= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100283618; called by muse, mutect2
- MCAM | c.1398C>A p.V466= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV50630647; called by muse, mutect2, varscan2
- MFAP3L | c.1227C>T p.V409= | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as COSV100852717, COSV64372449; called by muse, mutect2
- NCL | c.303C>A p.A101= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as COSV59547398; called by muse, mutect2
- NECTIN4 | c.918C>A p.T306= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100920048; called by muse, mutect2
- NEDD4L | c.2712G>T p.G904= (on ENST00000400345 / NM_001144967.3; = p.G884= on NM_015277.6) | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99896655; called by muse, mutect2
- NINL | c.243C>A p.R81= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV53999132, COSV54001894, COSV99626328; called by muse, mutect2, varscan2
- NMT2 | c.318C>A p.G106= | Silent (SNP) | VAF 11/173 reads (6%) | catalogued as COSV100975646; called by muse, mutect2
- OR5L2 | c.876G>A p.L292= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV65723481; called by muse, mutect2
- OR6B1 | c.651C>G p.S217= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV68769838; called by muse, mutect2, varscan2
- OSBPL1A | c.1788C>A p.L596= (on ENST00000319481 / NM_080597.4; = p.L83= on NM_018030.4) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV60195742; called by muse, mutect2, varscan2
- PANX1 | c.1266G>T p.L422= | Silent (SNP) | VAF 13/285 reads (5%) | catalogued as COSV99922051; called by muse, mutect2
- PCDHGA3 | c.1497G>T p.A499= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99536694; called by muse, mutect2
- PFDN1 | c.27G>A p.L9= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs754567365, COSV99945445; called by muse, mutect2, varscan2
- PHF3 | c.5457G>T p.G1819= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV100014028; called by muse, mutect2
- PLCB1 | c.1104G>T p.R368= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV100572232; called by muse, mutect2
- POLDIP3 | c.684C>A p.T228= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV52808234; called by muse, mutect2, varscan2
- POMGNT2 | c.777C>A p.V259= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV100768151; called by muse, mutect2
- RIPK2 | c.978G>A p.K326= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99610138; called by muse, mutect2
- SCYL3 | c.642C>A p.L214= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV100884323; called by muse, mutect2
- SHE | c.486C>A p.P162= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV100496226; called by muse, mutect2
- SIRPA | c.1173C>G p.L391= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1273821179, COSV100605426; called by muse, mutect2
- SMYD4 | c.702C>A p.S234= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV59710721; called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2
- TLE1 | c.2217C>A p.S739= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV100918980; called by muse, mutect2
- TM9SF4 | c.504G>T p.R168= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV54104852; called by muse, mutect2, varscan2
- TMEM163 | c.387C>A p.V129= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV56111971, COSV99927210; called by muse, mutect2
- TSACC | c.156G>T p.L52= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1323269460, COSV100966237; called by muse, mutect2
- TXN2 | c.123C>A p.G41= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99340567; called by muse, mutect2
- WDPCP | c.1302C>A p.A434= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV55414134; called by muse, mutect2, varscan2
- ZBED1 | c.429C>T p.I143= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs748804214, COSV100586090; called by muse, mutect2
- ZFHX4 | c.6804G>T p.R2268= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV50533885; called by muse, mutect2, varscan2
- ZFPM2 | c.45G>T p.P15= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV101343524, COSV68274572; called by muse, mutect2
- ZNFX1 | c.4323C>T p.C1441= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs775867313, COSV65594296; called by mutect2, varscan2
- ALMS1P1 | chr2:73700702 G>T | 3'Flank (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- ARRDC1 | chr9:137616011 C>T | 3'Flank (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446087 G>T | 3'Flank (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- GLRXP3 | n.311C>A | RNA (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- MFRP | chr11:119345430 G>T | 5'Flank (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100793550; called by muse, mutect2
- MGAM | c.4618+5541G>T | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as COSV101527768; called by muse, mutect2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 11/60 reads (18%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2, varscan2
